Gene-level copy-number profile of tumor specimen TCGA-13-1494-01A from TCGA case TCGA-13-1494, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 43.8 years (15,993 days).
Specimen TCGA-13-1494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.91d90e5d-92a7-43f2-88e5-e2a861b1d6a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1494-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98e08646-583b-495c-8ccb-4dbefa582cc7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 23,085; copy number 2: 31,401; copy number 3: 4,894; copy number 4: 145; copy number 5: 40; copy number 6: 227.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1494-01A-01D-0472-01): tumor purity 0.63, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:102,813,230–103,074,843, 1 gene (within-gene range 0–1): FBXL13.
- chr7:102,857,450–103,031,354, 4 genes: RN7SKP198, LRRC17, NFE4, AC073127.1.
- chr15:83,654,088–84,039,842, 1 gene (within-gene range 0–2): ADAMTSL3.
- chr15:83,824,863–83,962,583, 2 genes: RNU6-1339P, AC027807.2.
- chr22:27,676,559–27,721,677, 3 genes: AL121885.2, AL121885.3, AL121885.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 267 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:152,118,173–152,151,724, 1 gene, copy number 6: AC108718.1.
- chr3:152,245,262–152,269,557, 1 gene, copy number 6: MBNL1-AS1.
- chr6:10,980,759–11,644,343, 16 genes, copy number 5: ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP.
- chr6:87,720,915–87,721,018, 1 gene, copy number 5: AL133211.1.
- chr7:147,671,711–159,233,377, 248 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,174. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
